Gene-level copy-number profile of tumor specimen TCGA-D3-A3CF-06A from TCGA case TCGA-D3-A3CF, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 61.4 years (22,425 days).
Specimen TCGA-D3-A3CF-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.634efcc2-8b7d-4ca5-a5e1-b8a552540229.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A3CF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 397 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6665685b-6353-4c8c-8e8e-f098b7ce7b03

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 537; copy number 1: 8,511; copy number 2: 43,183; copy number 3: 6,236; copy number 4: 581; copy number 5: 314; copy number 6: 73; copy number 7: 189; copy number 8: 157; copy number 9: 26; copy number 10: 85; copy number 11: 64; copy number 12: 68; copy number 13: 13; copy number 14: 3; copy number 15: 9; copy number 16: 16; copy number 17: 17; copy number 18: 15; copy number 19: 27; copy number 20: 9; copy number 22: 7; copy number 24: 18; copy number 25: 4; copy number 26: 40; copy number 29: 1; copy number 30: 1; copy number 32: 9; copy number 33: 9; copy number 35: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A3CF-06A-11D-A194-01): tumor purity 0.22, ploidy 3.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,861,909, 6 genes: PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P, HNRNPCL1, PRAMEF2.
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.
- chr7:149,549–176,013, 3 genes: AC093627.4, AC093627.7, AC093627.2.
- chr8:40,298,697–40,353,133, 1 gene (within-gene range 0–2): SIRLNT.
- chr9:16,726,814–16,727,524, 1 gene: BNC2-AS1.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,178 genes in 62 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,230,030–12,777,906, 12 genes, copy number 5 (within-gene range 2–5): VPS13D, SNORA59A, LINC02766, DHRS3, RNU6ATAC18P, MIR6730, AC254633.1, AADACL4, AC244670.1, AADACL3, C1orf158, PRAMEF12.
- chr1:12,879,212–18,956,676, 177 genes, copy number 5 (broad region; genes not listed).
- chr1:24,040,835–25,113,120, 27 genes, copy number 5 (within-gene range 2–5): AL591178.1, MYOM3, MYOM3-AS1, IL22RA1, IFNLR1, LINC02800, GRHL3-AS1, GRHL3, STPG1, NIPAL3, RCAN3AS, RCAN3, NCMAP-DT, NCMAP, AL445686.1, Y_RNA, SRRM1, AL445648.1, CLIC4, RNU6-1208P, RUNX3, MIR6731, RUNX3-AS1, AL445471.1, MIR4425, LINC02793, AL050344.1.
- chr2:197,569–1,580,747, 32 genes, copy number 11–33 (within-gene range 1–33): AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO.
- chr2:2,870,558–3,536,873, 12 genes, copy number 13: AC011995.1, LINC01250, AC019118.2, AC019118.1, EIPR1, EIPR1-IT1, TRAPPC12, TRAPPC12-AS1, AC114810.1, ADI1, AC231981.1, AC108488.1.
- chr2:4,136,644–5,314,134, 6 genes, copy number 5–22: AC012445.1, NPM1P48, LINC01249, AC092169.1, RNU6-649P, AC073143.1.
- chr2:7,988,683–9,081,727, 12 genes, copy number 9–26: LINC00299, U91324.1, LINC01814, AC092617.1, AC011747.1, SNRPEP5, ID2-AS1, ID2, KIDINS220, MBOAT2, HMGB1P25, RPL30P3.
- chr2:12,411,398–12,742,734, 6 genes, copy number 6–16: RNU6-843P, AC096559.1, AC009486.2, AC009486.1, TRIB2, MIR3125.
- chr2:16,013,928–16,333,978, 7 genes, copy number 11 (within-gene range 1–31): GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3.
- chr2:16,853,820–17,123,140, 3 genes, copy number 5–25: AC008069.1, LINC01866, RN7SKP168.
- chr2:24,067,586–24,793,382, 18 genes, copy number 8–19: SF3B6, FAM228B, TP53I3, PFN4, AC008073.3, AC008073.2, FAM228A, AC008073.1, ITSN2, AC009228.1, AC009228.2, HMGN2P20, RPL36AP13, AC093798.1, NCOA1, RNA5SP88, RNU6-936P, PTRHD1.
- chr2:27,705,786–31,155,202, 55 genes, copy number 7–35 (within-gene range 2–35): LINC01460, MRPL33, RBKS, BABAM2, MYG1P1, MIR4263, FAM133EP, AC096552.1, AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7, AC074011.1, RNA5SP89, AC092164.1, PPP1CB, SPDYA, AC097724.1, TRMT61B, WDR43, SNORD92, SNORD53, Y_RNA, SNORD53B, TOGARAM2, Y_RNA, PCARE, AC105398.1, CLIP4, ALK, AC074096.1, RN7SL516P, AC106870.3, AC106870.2, AC106870.1, AC016907.2, AC016907.1, YPEL5, SNORA10B, H3P5, LBH, AC109642.1, LINC01936, AC073255.1, LCLAT1, AC132154.1, CAPN13, AC009301.1, GALNT14, AC009305.1.
- chr2:33,274,465–33,657,460, 10 genes, copy number 6 (within-gene range 3–6): AC019127.1, RNA5SP91, RNA5SP92, MIR4430, RASGRP3, RASGRP3-AS1, FAM98A, AC017050.1, ATP6V0E1P3, HNRNPA1P61.
- chr2:38,285,410–39,229,588, 29 genes, copy number 5–25 (within-gene range 5–40): GAPDHP25, ATL2, LINC02613, AC016995.1, LINC01883, RPLP0P6, AC011247.2, HNRNPLL, AC011247.1, GALM, AC074366.1, SRSF7, GEMIN6, TTC39DP, NPLP1, DHX57, ASS1P2, AC018693.1, MORN2, RNU6-851P, ARHGEF33, RN7SL96P, AC019171.1, SOS1, SOS1-IT1, RNU6-198P, HSPE1P13, Y_RNA, CDKL4.
- chr2:97,000,436–97,589,965, 28 genes, copy number 5: AC079395.3, AC079395.2, AC079395.1, TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2, IGKV1OR2-3, GPAT2P2, FAHD2B, AC018892.3, RN7SL313P, ANKRD36, AC159540.2, AC159540.1, IGKV1OR2-9, IGKV2OR2-10, IGKV2OR2-7D, IGKV3OR2-5, IGKV1OR2-6, IGKV2OR2-7, IGKV2OR2-8, IGKV1OR2-11, AC092683.1, AC092683.2, ANKRD36B, AC017099.1.
- chr5:1,225,381–1,345,099, 5 genes, copy number 9 (within-gene range 1–9): SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L.
- chr5:4,866,521–5,320,304, 10 genes, copy number 7–13: AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1.
- chr5:13,690,331–17,670,571, 88 genes, copy number 7–32 (within-gene range 3–32) (broad region; genes not listed).
- chr5:18,236,123–23,528,093, 40 genes, copy number 6–25: SNORD81, RN7SL58P, LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1.
- chr5:26,669,346–29,217,115, 21 genes, copy number 5–24 (within-gene range 3–28): AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4.
- chr5:32,531,633–32,656,022, 3 genes, copy number 17 (within-gene range 3–17): SUB1, LINC02061, AC008766.1.
- chr5:35,852,695–36,001,028, 6 genes, copy number 5: IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1.
- chr5:41,306,952–42,721,878, 15 genes, copy number 17–18 (within-gene range 3–32): PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1.
- chr5:94,567,461–95,961,851, 29 genes, copy number 6–10 (within-gene range 6–17): MTND5P12, MTND6P3, MTCYBP35, AC093311.1, AC025766.1, SLF1, MCTP1, AC008534.1, RPL7P18, AC008534.2, MCTP1-AS1, FAM81B, RTRAFP2, TTC37, RNU6-308P, ARSK, GPR150, RFESD, SPATA9, AC008840.1, RHOBTB3, GLRX, HSPD1P11, GGCTP1, AC008592.3, LINC01554, AC008592.4, AC008592.1, ELL2.
- chr5:95,964,999–96,278,751, 7 genes, copy number 10: AC008592.2, FABP5P5, MIR583HG, MIR583, RNU6-524P, AC099509.1, AC099509.2.
- chr5:96,935,394–97,449,741, 14 genes, copy number 12: LNPEP, AC008850.1, Y_RNA, SETP22, LIX1-AS1, LIX1, RIOK2, RNU1-73P, AC008883.3, AC008883.1, AC008883.2, AC074133.1, YTHDF1P1, AC106748.1.
- chr5:98,085,866–98,995,013, 19 genes, copy number 7 (within-gene range 4–7): LINC01846, AC116347.1, PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1.
- chr5:101,581,830–106,417,241, 35 genes, copy number 5–11: RN7SL802P, OR7H2P, AC117525.1, RNA5SP188, AC008948.1, SLCO4C1, RN7SKP68, SLCO6A1, AC094108.1, LINC00492, LINC00491, AC099487.1, AC099487.2, PAM, EIF3KP1, GIN1, PPIP5K2, AC011362.1, MACIR, AC010406.1, PDZPH1P, LINC02115, NUDT12, AC008505.1, LINC02163, RNU1-140P, RN7SL255P, AC099520.1, AC091931.1, AC099520.2, RNU6-334P, AC091987.1, RAB9BP1, RNA5SP189, AC027313.1.
- chr5:106,815,197–111,997,464, 55 genes, copy number 5–8 (within-gene range 1–8): LINC01950, PSMC1P5, EFNA5, AC024587.2, AC024587.1, RN7SL782P, RN7SKP122, FBXL17, AC008462.1, AC133134.1, LINC01023, FER, AC034207.1, AC008871.1, Y_RNA, AC109481.1, RNU6-47P, GJA1P1, AC116428.1, AC008467.1, PJA2, AC010625.1, AC091917.3, AC091917.2, AC091917.1, KRT18P42, MAN2A1-DT, MAN2A1, RN7SKP230, AC008417.1, LINC01848, PGAM5P1, TMEM232, MIR548F3, AC008650.1, SLC25A46, AC008782.1, BCLAF1P1, AC010395.1, AC010395.2, TSLP, AC008572.1, WDR36, AC010468.2, RPS3AP21, CAMK4, AC010468.1, AC010275.1, STARD4, STARD4-AS1, HMGN1P13, AC008967.1, NREP, RN7SKP57, HMGN1P14.
- chr5:116,716,243–117,330,149, 7 genes, copy number 7: RPS17P2, LINC02214, AC010267.1, AC093534.1, AC093534.2, RPL35AP15, AC093295.1.
- chr5:121,851,882–123,236,370, 25 genes, copy number 7–10: FTMT, SRFBP1, LOX, AC010255.1, ZNF474, AC010255.2, ZNF474-AS1, AC113349.2, SNCAIP, AC113349.1, AC119150.1, AC119150.2, MGC32805, LINC02201, ARGFXP1, SNX2, AC008669.1, SNX24, RN7SL689P, PPIC, PPIC-AS1, RN7SL711P, AC106786.1, PRDM6, AC010493.1.
- chr5:124,395,603–124,536,348, 5 genes, copy number 5: AC016556.1, AC025465.2, AC025465.4, AC025465.3, AC025465.1.
- chr5:126,867,714–127,143,247, 4 genes, copy number 11 (within-gene range 1–11): MARCHF3, C5orf63, AC005915.1, MRPS5P3.
- chr5:127,465,822–128,083,172, 11 genes, copy number 6–8 (within-gene range 3–8): AC010424.1, AC010424.2, HNRNPKP1, PRRC1, AC010424.3, CTXN3, AC022118.1, CCDC192, CUL1P1, AC068658.1, LINC01184.
- chr5:129,904,465–130,186,634, 4 genes, copy number 12: CHSY3, RNU6ATAC10P, RNA5SP191, HSPA8P4.
- chr5:139,795,808–140,828,549, 45 genes, copy number 10: PSD2, NRG2, AC008667.2, Y_RNA, MALINC1, PURA, IGIP, AC011379.2, CYSTM1, AC011379.1, PFDN1, HBEGF, AC008438.2, SLC4A9, AC008438.1, RNU4-14P, ANKHD1, ANKHD1-EIF4EBP3, AC011399.1, SRA1, EIF4EBP3, APBB3, AC116353.5, MIR6831, SLC35A4, AC116353.6, AC116353.1, HAUS1P1, AC116353.2, CD14, NDUFA2, TMCO6, IK, MIR3655, WDR55, DND1, HARS1, HARS2, ZMAT2, VTRNA1-1, VTRNA1-2, VTRNA1-3, AC116353.4, AC116353.3, AC005609.5.
- chr5:147,585,438–147,923,421, 9 genes, copy number 5 (within-gene range 1–5): JAKMIP2, AC011370.1, SPINK1, AC011352.2, SCGB3A2, C5orf46, AC011352.1, AC011352.3, EEF1GP2.
- chr5:178,237,618–179,083,977, 28 genes, copy number 5–11 (within-gene range 3–11): COL23A1, AC136601.2, AC136601.1, RN7SL646P, AC008659.1, CLK4, RN7SKP70, AC113348.3, AC113348.1, AC113348.2, ZNF354A, AACSP1, AC126915.2, AC126915.1, AC126915.3, ZNF354B, RNU1-39P, ZFP2, AC104117.1, PIGFP1, AC104117.5, ZNF454, AC104117.3, GRM6, AC104117.4, ZNF879, ZNF354C, AC104117.2.
- chr14:105,785,505–106,360,324, 101 genes, copy number 7 (broad region; genes not listed).
- chr15:19,878,555–22,282,872, 128 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,511. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
